Surgical pathology report (de-identified scan), TCGA case TCGA-NJ-A4YG, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Rush University, specimen TCGA-NJ-A4YG-01A (Primary Tumor).

[page 1 of 8]
Procedure Location:

ICD-O-3

Path: Adenocarcinoma, NOS 8140/3

CQCF: Adenocarcinoma, with mixed subtypes 8255/3

Site: Lung, ^(C)upper lobe C34.1

hw
10/31/12

PATHOLOGY SURGICAL

Results

Entry Date

[page 2 of 8]
Component Results

PATHOLOGY RESULT:

Department of Pathology

Final

Clinical Data Repository* This report may not match the original report
format

FINAL DIAGNOSIS

A. (Lymph node, level 10; biopsy): Fragments of lymph node, negative for malignancy.

[page 3 of 8]
B. (Lymph node, level 11; biopsy): Fragments of lymph node, negative for malignancy.

C. (Lung, left upper lobe; lobectomy): Infiltrating moderately differentiated adenocarcinoma measuring 1.9 cm, with extension to the visceral pleura. Bronchial and vascular margins free of tumor. Five perihilar lymph nodes negative for malignancy. No convincing lymphovascular invasion seen. Stage pT2N0MX.

D. (Lymph node, level 5; biopsy): Fragments of lymph node, negative for malignancy.

E. (Lymph node, level 6; biopsy): Fragments of lymph node, negative for malignancy.

F. (Lymph node, level 10R; biopsy): Fragments of lymph node, negative for malignancy.

INTRAOPERATIVE CONSULTATION

C. LEFT UPPER LOBE- FROZEN BRONCHIAL MARGIN: Adenocarcinoma. Bronchial margin is negative for malignancy. (Frozen section C91, C92, touch prep and smear)

[page 4 of 8]
GROSS DESCRIPTION

A. The specimen is labeled level 10 lymph node. Received fresh is a 0.5 x 0.4 x 0.3 cm segment of black fibrofatty tissue. The specimen is entirely submitted in cassette A1.

B. The specimen is labeled level 11 lymph node. Received fresh are multiple fragments of blackish-pink tissue, altogether measuring 0.5 x 0.4 x 0.3 cm. The specimen is wrapped and entirely submitted in cassette B1.

C. The specimen is labeled left upper lobe. Received fresh for frozen section, is a 220 gram, 18.0 x 9.0 x 3.0 cm lobectomy specimen with a 4.0 cm stapled margin. A 1.9 x 1.8 x 0.8 cm tan, firm mass is seen in the central portion of the lobe with retraction of the pleural surface. A representative section of the mass is submitted for frozen section, and the remnant is placed in cassette C92. The bronchial margin is submitted for frozen section and the remnant is placed in cassette C91. The remainder of the lung is serially sectioned and shows patchy pale areas, but no lesions or masses. Sections are submitted as follow: C1 vascular margins, C2 perihilar lymph nodes, C3 tumor and adjacent lung, C4 tumor, C5 uninvolved lung, C6 stapled margin.

[page 5 of 8]
D. The specimen is labeled level 5 lymph node. Received fresh is a fragment of fibrofatty tissue, measuring 2.0 x 1.0 x 0.5 cm. The specimen is entirely submitted in cassette D1.

E. The specimen is labeled level 6 lymph node. Received fresh are multiple fragments of fibrofatty tissue, altogether measuring 0.8 x 0.3 x 0.3 cm. The specimen is entirely submitted in cassette E1.

F. The specimen is labeled level 10R lymph node. Received fresh is a 0.6 x 0.5 x 0.3 cm fragment of fibrofatty tissue. The specimen is bisected and submitted in cassette F1.

SPECIMEN(S) RECEIVED

A: LEVEL 10 LYMPH NODE

B: FRESH ROUTINE LEVEL 11 LYMPH NODE

C: LEFT UPPER LOBE- FROZEN BRONCHIAL MARGIN

D: LEVEL 5 LYMPH NODE- FRESH ROUTINE

E: LEVEL 6 LYMPH NODE-FRESH ROUTINE

F: FRESH ROUTINE - LEVEL 10R LYMPH NODE

* The above listed tests (if any) were developed and the performance

characteristics determined . ,

These tests have

[page 6 of 8]
not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays.

OPERATIVE INFORMATION

DIAGNOSIS: LUNG MASS; PROCEDURE: BRONCHOSCOPY FLEXIBLE FIBEROPTIC,
THORACOSCOPY VIDEO ASSISTED

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s): .

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

PATHOLOGY SURGICAL

- Lab and Collection Information

[page 7 of 8]
Pathology

Procedure Location:

Dx discrepancy form attached .

	Yes ☒	No ☐
Discrepancy		☒
Copy		☒
Primary Noted		☒

JAC [Signature]

[page 8 of 8]
TCGA Pathologic Diagnosis Discrepancy Form

V.0.01

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____

TSS Identifier: _____

TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____

Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Infiltrating moderately differentiated Adenocarcinoma with extension to the visceral pleura.	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Mixed: acinar, papillary	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Path report does not list subtype	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Date

Source: NCI Genomic Data Commons file 28508a16-27ce-4e12-ba17-37673507d1c9 (TCGA-NJ-A4YG.6A90E23E-9E8F-4282-837C-120E3AE994D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).